Somatic mutation profile of tumor specimen TARGET-40-NAAGKG-01A (aliquot TARGET-40-NAAGKG-01A-01D) from TARGET case TARGET-40-NAAGKG, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 18.3 years (6,683 days).
Specimen TARGET-40-NAAGKG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 343d2e5d-ffc5-4ff1-b4e5-cb88514294c9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGKG-10B (Blood Derived Normal), aliquot TARGET-40-NAAGKG-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e9d61a8-2a9c-4edb-b69f-5d341587fa07

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCLO | c.5114C>A p.T1705K | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1000697594; called by muse, mutect2, varscan2
- PLXNA3 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as rs782215325, COSV100859888; called by muse, mutect2, varscan2
- TTN | c.59272G>C p.D19758H (on ENST00000591111; = p.D12334H on NM_003319.4) | Missense Mutation (SNP) | VAF 86/118 reads (73%) | PolyPhen probably damaging (0.971); catalogued as COSV100622312; called by muse, varscan2
- CCDC168 | c.7981C>T p.P2661S | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.235); called by muse, mutect2
- COL1A1 | c.2667+1_2667+2del p.X889_splice | Splice Site (DEL) | VAF 7/30 reads (23%) | called by mutect2, pindel
- FAT1 | c.5684G>C p.G1895A | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL1RAPL2 | c.1332C>G p.F444L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); called by muse, mutect2
- SLC26A4 | c.1411C>T p.L471= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs1224848656, COSV55917378; called by muse, mutect2, varscan2
